Gene-level copy-number profile of tumor specimen ALCH-ADI3-TTP1-A from ALCHEMIST case ALCH-ADI3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 47.8 years (17,441 days).
Specimen ALCH-ADI3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 38fb8b46-2cf6-4099-814f-eb33e5222331.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADI3-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/184aff70-a821-4cb4-a377-afe0511de3fd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 38; copy number 1: 7,079; copy number 2: 40,480; copy number 3: 9,652; copy number 4: 523; copy number 5: 182; copy number 6: 40; copy number 7: 14; copy number 8: 69; copy number 9: 25; copy number 10: 219; copy number 11: 6; copy number 13: 57; copy number 15: 5; copy number 19: 12; copy number 25: 1.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,811,359–143,825,837, 1 gene: AC239798.1.
- chr9:10,777,357–12,058,227, 7 genes: AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL592227.1, AL353595.1.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–1): AL359922.1.
- chr9:21,929,457–23,956,444, 23 genes (within-gene range 0–1): ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3.
- chr14:73,537,143–73,543,796, 2 genes (within-gene range 0–2): ACOT1, NT5CP2.
- chr17:22,266,395–22,332,410, 4 genes: AC138761.1, AC138761.2, FAM27E5, AC087575.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 630 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,498,767, 5 genes, copy number 8: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1.
- chr1:143,905,487–143,934,776, 1 gene, copy number 9 (within-gene range 1–9): AC246680.1.
- chr5:58,198–7,326,609, 138 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr5:8,080,186–9,546,075, 30 genes, copy number 5–6 (within-gene range 3–6): AC091941.1, AC091912.2, AC091912.1, AC091912.3, LINC02226, AC091965.1, AC091965.3, AC091965.4, MIR4458HG, AC091965.2, AC091965.5, MIR4458, AC091953.1, AC091953.3, AC091953.5, MTND6P2, MTCYBP37, AC091953.2, AC091953.6, AC091953.4, AC091932.4, AC091932.2, AC091932.1, AC091932.3, LINC02199, AC091895.1, AC021088.1, SEMA5A, MIR4636, AC091906.1.
- chr5:24,352,309–24,644,978, 5 genes, copy number 5: AC010387.1, Metazoa_SRP, CDH10, AC091885.2, AC091885.1.
- chr7:48,171,458–56,955,864, 141 genes, copy number 6–10 (broad region; genes not listed).
- chr8:87,974,165–88,019,113, 1 gene, copy number 5: AC037450.1.
- chr8:101,461,177–103,501,895, 55 genes, copy number 5 (within-gene range 2–5): AP001207.3, GRHL2, AP001207.2, AP001207.1, NCALD, AP000426.1, AP001329.1, PDCL3P2, MIR5680, AP001328.1, RRM2B, UBR5-AS1, SUMO2P19, UBR5, AP002907.1, AP002981.1, RNU6ATAC8P, HSPE1P14, RPS12P15, AP002852.1, RNU6-1224P, ODF1, POU5F1P2, KLF10, ADI1P2, GASAL1, AZIN1, AP003696.1, MAILR, AP003354.1, RPL5P24, Y_RNA, NPM1P52, AP003550.1, ATP6V1C1, MTND1P5, MTCO1P4, MTCO2P4, LINC01181, BAALC-AS2, BAALC, BAALC-AS1, MIR3151, AC025370.1, FZD6, AC025370.2, CTHRC1, AC012213.3, RNU6-1011P, SLC25A32, AC012213.5, DCAF13, AC012213.2, AC012213.4, AC012213.1.
- chr8:113,950,886–117,540,262, 25 genes, copy number 5: Y_RNA, AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16.
- chr8:119,873,717–120,050,918, 1 gene, copy number 5 (within-gene range 4–5): DEPTOR.
- chr8:120,052,180–120,813,359, 8 genes, copy number 5: AC091563.1, COL14A1, MRPL13, MTBP, SNTB1, NCAPGP1, AC104958.1, AC104958.2.
- chr14:25,647,304–26,143,305, 1 gene, copy number 13 (within-gene range 3–13): LINC02306.
- chr14:25,916,015–40,390,547, 219 genes, copy number 6–25 (within-gene range 3–25) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,079. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
